Somatic mutation profile of tumor specimen 0DEV4P from CCDI case PBBPNU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,102 days).
Specimen 0DEV4P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f21bf59b-7758-432d-95fa-b1009b569c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b746c57d-4be7-4db3-a744-303ba754aeba

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 1, Intron 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 257/476 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 163/588 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 185/220 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52674926, COSV52693942, COSV52759722; called by muse, mutect2, varscan2
- MAPRE1 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 163/393 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.248); catalogued as rs778221336, COSV65032632; called by muse, mutect2, varscan2
- PAPOLG | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 31/560 reads (6%) | catalogued as COSV53181672; called by muse, mutect2
- AADACL4 | c.500T>C p.M167T | Missense Mutation (SNP) | VAF 297/646 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AVPR1B | c.971T>C p.M324T | Missense Mutation (SNP) | VAF 247/402 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- LMNB1 | c.1524C>A p.S508R | Missense Mutation (SNP) | VAF 117/312 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZFPM1 | c.1301C>G p.A434G | Missense Mutation (SNP) | VAF 60/716 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.186); called by muse, mutect2
- ZNF525 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 95/161 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- BRD1 | c.2703C>T p.Y901= (on ENST00000216267 / NM_001349940.1; = p.Y1032= on NM_001304808.3) | Silent (SNP) | VAF 242/560 reads (43%) | catalogued as rs370621351; called by muse, mutect2
- EYS | c.1767-8250T>C | Intron (SNP) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- PSG2 | c.-11C>A | 5'UTR (SNP) | VAF 121/259 reads (47%) | called by muse, varscan2
